Somatic mutation profile of cancer-model specimen HCM-SANG-0303-C15-85A (3D Organoid; aliquot HCM-SANG-0303-C15-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0303-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0303-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5a05f4a-a3d9-44dd-afc5-3afd14e7335b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0303-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0303-C15-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f544160-17f2-478a-86c0-6223fa726985

The open-access MAF lists 332 somatic variants for this specimen: 230 protein-altering or splice-affecting, 61 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 203, Silent 61, Intron 18, Nonsense Mutation 9, 5'UTR 6, RNA 6, 3'UTR 5, Frame Shift Del 5, Frame Shift Ins 5, 5'Flank 5, In Frame Del 3, Splice Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 246/247 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 325/326 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TSHR | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 138/249 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.784); catalogued as rs121908882, CM002872, COSV53318872; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ACAP3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs752033058; called by muse, mutect2, varscan2
- ADAMTS13 | c.3253T>A p.S1085T | Missense Mutation (SNP) | VAF 127/234 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52470444; called by muse, mutect2, varscan2
- ADAMTS7 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 314/594 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs771557466, COSV66308555; called by muse, mutect2, varscan2
- ADGRL3 | c.4562C>T p.A1521V (on ENST00000506720 / NM_001322402.2; = p.A1410V on NM_015236.6) | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.309); catalogued as rs1362194765; called by muse, mutect2, varscan2
- AMFR | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1313900274, COSV51922948; called by muse, mutect2, varscan2
- AP3B2 | c.2844C>A p.F948L (on ENST00000261722; = p.F942L on NM_004644.5) | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99916294; called by muse, mutect2, varscan2
- AQP11 | c.254_256del p.F85del | In Frame Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs747275160; called by pindel, varscan2
- BAIAP3 | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs754394948, COSV50104328, COSV50105887; called by muse, mutect2, varscan2
- BRAT1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs368710298; called by muse, mutect2, varscan2
- C2CD4A | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1437087276; called by muse, mutect2, varscan2
- CCDC157 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs1322912646; called by muse, mutect2, varscan2
- CCM2L | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 38/810 reads (5%) | catalogued as rs1377020656; called by muse, mutect2
- CDC25A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs757533603, COSV56770671; called by muse, mutect2, varscan2
- CDH13 | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs754962424, COSV99232015; called by muse, mutect2, varscan2
- CNBD1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 16/125 reads (13%) | catalogued as rs1439285638; called by muse, mutect2, varscan2
- CNTN4 | c.2444C>A p.A815D | Missense Mutation (SNP) | VAF 227/380 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs759872185; called by muse, mutect2, varscan2
- COL6A3 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 281/388 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs775165275; called by muse, mutect2, varscan2
- COL6A5 | c.4874T>G p.L1625R | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV99594947; called by muse, mutect2, varscan2
- CTRC | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 175/391 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780706590; called by muse, mutect2, varscan2
- ELOA2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 326/803 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767426854, COSV55294620; called by muse, mutect2, varscan2
- ERVMER34-1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1023317331, COSV101192644; called by muse, mutect2, varscan2
- ETV1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433178930, COSV54148351; called by muse, mutect2, varscan2
- FAM170A | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs775441770, COSV58926608; called by muse, mutect2, varscan2
- FGF13 | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 119/120 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV59550984; called by muse, mutect2, varscan2
- FGF18 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 171/353 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs376004950; called by muse, mutect2, varscan2
- FGFR1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as CM1410279; called by muse, mutect2, varscan2
- FKBP5 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 113/266 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs148272640; called by muse, mutect2, varscan2
- FRMD6 | c.1004G>A p.R335Q (on ENST00000344768 / NM_001267046.2; = p.R327Q on NM_152330.4) | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as rs1016945695, COSV61089462; called by muse, mutect2
- GALC | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.997); catalogued as rs1379802641; called by muse, mutect2
- GK | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 226/230 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66734377; called by muse, mutect2, varscan2
- H3C3 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as rs747063074; called by muse, mutect2, varscan2
- HPS5 | c.3103C>A p.L1035I (on ENST00000349215 / NM_181507.2; = p.L921I on NM_007216.4) | Missense Mutation (SNP) | VAF 295/418 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61687020; called by muse, mutect2, varscan2
- IGSF10 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs567335058, COSV56782916; called by muse, mutect2, varscan2
- IRGC | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 139/419 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1162537052; called by muse, mutect2, varscan2
- ITM2B | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 138/590 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1348993810; called by muse, mutect2, varscan2
- KCNJ12 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 243/1204 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.063); catalogued as rs1433170217, COSV100054023, COSV59167049; called by muse, varscan2
- KIR2DL1 | c.251A>G p.N84S | Missense Mutation (SNP) | VAF 352/823 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV99383104; called by muse, mutect2, varscan2
- KRT4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs199642796; called by muse, mutect2, varscan2
- LAMA4 | c.946G>A p.A316T (on ENST00000230538 / NM_001105206.3; = p.A309T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/545 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs782110284; called by muse, mutect2, varscan2
- LAMC3 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 267/517 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs376335879; called by muse, mutect2, varscan2
- LIMK1 | c.1837G>A p.G613S | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs368807700; called by muse, mutect2, varscan2
- LYRM1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs200822121; called by muse, mutect2, varscan2
- MCF2 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MCHR2 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99911442, COSV99912012; called by muse, mutect2
- MKX | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1223669362, COSV101008548, COSV65391384; called by muse, mutect2, varscan2
- MLH1 | c.1614G>C p.W538C | Missense Mutation (SNP) | VAF 122/246 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as CM994509, COSV51618014; called by muse, mutect2, varscan2
- MORC4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs773446384, COSV55240307, COSV55241225; called by muse, mutect2, varscan2
- MYH1 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 170/172 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374097415; called by muse, mutect2, varscan2
- MYO3A | c.1588T>C p.Y530H | Missense Mutation (SNP) | VAF 189/294 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56329729; called by muse, mutect2, varscan2
- NIF3L1 | c.691C>T p.L231F (on ENST00000409020 / NM_001369444.1; = p.L204F on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs557770526; called by muse, mutect2, varscan2
- NPS | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986285118, COSV67690790; called by muse, mutect2, varscan2
- NUTM2E | c.2038G>A p.D680N | Missense Mutation (SNP) | VAF 297/597 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); catalogued as rs1414100585; called by mutect2, varscan2
- OR10A3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs140281755; called by muse, mutect2, varscan2
- OR2T4 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs772005496; called by muse, mutect2, varscan2
- OR5M11 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1257337927, COSV73141788; called by muse, mutect2, varscan2
- OR5T3 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV57382916; called by muse, mutect2, varscan2
- PCDHA13 | c.1546A>C p.K516Q | Missense Mutation (SNP) | VAF 120/773 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.817); catalogued as rs782678422; called by muse, mutect2, varscan2
- PCDHGC3 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs778851755; called by muse, mutect2, varscan2
- PDGFC | c.817G>C p.G273R | Missense Mutation (SNP) | VAF 46/482 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.549); catalogued as COSV56849212; called by muse, mutect2
- PEX19 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 210/690 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs149976198, COSV63620161; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1CC | c.680T>C p.F227S | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58582406; called by muse, mutect2
- PRPS1L1 | c.890C>A p.A297E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1243439903; called by muse, mutect2, varscan2
- PTP4A3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 111/185 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV61472529; called by muse, mutect2, varscan2
- PTPRN2 | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs373071385; called by muse, mutect2, varscan2
- PTPRU | c.3529C>T p.R1177W | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs761647543, COSV100113375; called by muse, mutect2, varscan2
- RBAK | c.1151G>C p.R384P | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62331951; called by muse, mutect2, varscan2
- RBBP8NL | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 90/725 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs200596881, COSV53348543; called by muse, varscan2
- RECQL5 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs766459582; called by muse, mutect2
- RIMS1 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1490525212, COSV53489745; called by muse, mutect2, varscan2
- RXFP3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 105/194 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as rs1257769979, COSV57505702; called by muse, mutect2, varscan2
- SALL3 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs758917162, COSV101609999; called by muse, mutect2, varscan2
- SBK2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as rs1397000946; called by muse, mutect2, varscan2
- SH3TC1 | c.2995G>A p.V999I | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as rs77050840; called by muse, mutect2, varscan2
- SHANK1 | c.1505G>A p.R502Q | Missense Mutation (SNP) | VAF 209/499 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.886); catalogued as rs766019271; called by muse, mutect2, varscan2
- SLC26A8 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 126/154 reads (82%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs200862862; called by muse, mutect2, varscan2
- SLC4A5 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs764542611; called by muse, mutect2, varscan2
- SLITRK3 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs768765994, COSV99578959; called by muse, mutect2, varscan2
- SPATA18 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 143/267 reads (54%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV54651164; called by muse, mutect2, varscan2
- SRRM2 | c.3188C>G p.T1063S | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1227075086; called by muse, mutect2, varscan2
- SUPV3L1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1284322599; called by muse, mutect2
- TEP1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.145); catalogued as COSV52997235; called by muse, mutect2, varscan2
- THBS2 | c.3277C>G p.R1093G | Missense Mutation (SNP) | VAF 160/190 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV64681572; called by muse, mutect2, varscan2
- TLR6 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs372338548; called by muse, mutect2, varscan2
- TMEM121B | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 189/422 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.668); catalogued as COSV100083507, COSV58898441; called by muse, mutect2
- TMEM198 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 133/635 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as rs765960749; called by muse, mutect2, varscan2
- TMEM219 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs781591004; called by muse, mutect2, varscan2
- TNC | c.6085C>T p.R2029C | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261019634, COSV100404726; called by muse, mutect2, varscan2
- TNIK | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs765841993, COSV52693092; called by muse, mutect2
- TRHDE | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as COSV53870606; called by muse, mutect2, varscan2
- TRHDE | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs746039335; called by muse, mutect2, varscan2
- TRIM10 | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs777984807, COSV64998640; called by muse, mutect2, varscan2
- TRIM51 | c.1339T>G p.F447V | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV99792639; called by muse, mutect2, varscan2
- TRUB1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs768178093, COSV100076126, COSV53930791; called by muse, mutect2, varscan2
- TUBA3C | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1366301992, COSV67139693; called by muse, mutect2, varscan2
- TUBB4B | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 281/628 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV61116984; called by muse, mutect2, varscan2
- UBAP2L | c.823A>G p.T275A | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.935); catalogued as rs926209216; called by muse, mutect2, varscan2
- VWA8 | c.3463G>C p.D1155H | Missense Mutation (SNP) | VAF 162/596 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV64996849; called by muse, mutect2, varscan2
- WDR49 | c.1361T>G p.L454R (on ENST00000308378 / NM_001366158.1; = p.L795R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57705031; called by muse, mutect2, varscan2
- ZNF341 | c.1654C>T p.P552S (on ENST00000375200 / NM_001282935.1; = p.P545S on NM_032819.4) | Missense Mutation (SNP) | VAF 91/608 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs144552809; called by muse, mutect2, varscan2
- AC114490.3 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ADAM15 | c.334C>G p.H112D | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADAM3A | n.1010-1G>T | Splice Site (SNP) | VAF 100/124 reads (81%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.2882G>A p.C961Y | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.220A>G p.N74D | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFF2 | c.586T>G p.F196V | Missense Mutation (SNP) | VAF 185/186 reads (99%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ANKRD17 | c.1142A>C p.E381A | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.246); called by muse, mutect2
- ARFGEF1 | c.1802G>A p.S601N | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASTN1 | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 92/137 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ASXL2 | c.2333dup p.V779Sfs*25 | Frame Shift Ins (INS) | VAF 132/248 reads (53%) | called by mutect2, varscan2
- ATAD2B | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AUH | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- B3GALNT1 | c.592A>C p.N198H | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- C1QL4 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CAPN13 | c.1428A>C p.K476N | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- CASP8AP2 | c.5885C>A p.P1962Q | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CCDC141 | c.4119G>C p.R1373S | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC39 | c.2483T>G p.L828R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCM2L | c.1070-5C>T | Splice Region (SNP) | VAF 61/592 reads (10%) | called by muse, mutect2, varscan2
- CEP120 | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 23/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CLEC2D | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 117/206 reads (57%) | SIFT tolerated (0.98); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLTC | c.4069C>G p.L1357V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL11A1 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRB1 | c.3584T>G p.V1195G | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CSMD3 | c.7259G>T p.R2420M (on ENST00000297405 / NM_001363185.1; = p.R2316M on NM_052900.3) | Missense Mutation (SNP) | VAF 186/298 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTIF | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CYP3A4 | c.1137dup p.D380Rfs*3 | Frame Shift Ins (INS) | VAF 135/587 reads (23%) | called by mutect2, pindel, varscan2
- DCP1B | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 110/240 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DEPDC4 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DNAH11 | c.825A>T p.Q275H | Missense Mutation (SNP) | VAF 87/346 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DNAH11 | c.7198G>T p.E2400* | Nonsense Mutation (SNP) | VAF 220/503 reads (44%) | called by muse, mutect2, varscan2
- DNAJB6 | c.104A>C p.N35T | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DTNA | c.1150C>G p.P384A | Missense Mutation (SNP) | VAF 188/365 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EMID1 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 85/197 reads (43%) | called by muse, mutect2, varscan2
- EMILIN3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.116); called by muse, mutect2
- ERBB4 | c.836T>G p.F279C | Missense Mutation (SNP) | VAF 224/317 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- ERVV-2 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 244/520 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EXOC6 | c.1913_1914insG p.N638Kfs*41 | Frame Shift Ins (INS) | VAF 53/115 reads (46%) | called by mutect2, pindel, varscan2
- FAM124A | c.1213G>A p.D405N (on ENST00000322475 / NM_001242312.2; = p.D441N on NM_145019.4) | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM135B | c.3161G>T p.R1054M | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FBLN7 | c.788C>G p.A263G | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FFAR3 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 282/1159 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- FILIP1L | c.2855C>T p.A952V (on ENST00000354552 / NM_182909.3; = p.A712V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- FNIP1 | c.2614A>G p.I872V | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXP1 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GFM2 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR85 | c.860_862del p.F287del | In Frame Del (DEL) | VAF 94/229 reads (41%) | called by mutect2, pindel, varscan2
- H2AC16 | c.235A>C p.I79L | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- HDC | c.220A>G p.S74G | Missense Mutation (SNP) | VAF 161/299 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HELZ2 | c.4067C>A p.A1356D (on ENST00000467148 / NM_001037335.2; = p.A787D on NM_033405.3) | Missense Mutation (SNP) | VAF 29/680 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IBTK | c.2249C>G p.A750G | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IGFN1 | c.2124T>A p.H708Q (on ENST00000295591 / NM_001367841.1; = p.H3165Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2
- IGKV3D-11 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 167/448 reads (37%) | called by muse, mutect2, varscan2
- ISL2 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 128/229 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- JAKMIP1 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNJ1 | c.871T>C p.F291L | Missense Mutation (SNP) | VAF 395/575 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNJ8 | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- LONP2 | c.2132A>G p.Y711C | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRGUK | c.1103A>T p.E368V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRP4 | c.5135A>G p.D1712G | Missense Mutation (SNP) | VAF 484/747 reads (65%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC69 | c.86T>A p.M29K | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- LTN1 | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by mutect2, varscan2
- MACC1 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 313/314 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACROD1 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 74/296 reads (25%) | called by muse, mutect2, varscan2
- MACROD1 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 71/294 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MALRD1 | c.6366C>A p.N2122K | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- MAP2K3 | c.596A>G p.N199S (on ENST00000342679 / NM_145109.3; = p.N170S on NM_002756.4) | Missense Mutation (SNP) | VAF 82/465 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- MEIOC | c.1379T>G p.L460* | Nonsense Mutation (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- METTL21C | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- MSH5 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MUC16 | c.13297A>C p.S4433R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- MYO3B | c.201A>C p.E67D | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NAA30 | c.1066C>G p.R356G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- NKX1-1 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 74/171 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- NLGN4X | c.477del p.H160Mfs*25 | Frame Shift Del (DEL) | VAF 50/185 reads (27%) | called by mutect2, pindel, varscan2
- NPY5R | c.616T>A p.S206T | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NRXN1 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 52/78 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- NUTM1 | c.2364T>A p.C788* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- NUTM2E | c.2039A>C p.D680A | Missense Mutation (SNP) | VAF 298/588 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.267); called by mutect2, varscan2
- OGFRL1 | c.1101dup p.V368Sfs*20 | Frame Shift Ins (INS) | VAF 65/185 reads (35%) | called by mutect2, pindel, varscan2
- OLFM3 | c.1307A>C p.N436T (on ENST00000338858 / NM_001288821.1; = p.N416T on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR10D3 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 137/552 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR5M11 | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- ORAI3 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 147/305 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PCDH15 | c.-28-2A>T | Splice Site (SNP) | VAF 99/198 reads (50%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1157A>T p.N386I | Missense Mutation (SNP) | VAF 172/344 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHB10 | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.101); called by muse, varscan2
- PCDHB2 | c.2380del p.S794Afs*8 | Frame Shift Del (DEL) | VAF 28/76 reads (37%) | called by mutect2, pindel, varscan2
- PHKA1 | c.3214T>C p.Y1072H | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNPLA6 | c.328A>G p.K110E (on ENST00000414982 / NM_001166111.2; = p.K62E on NM_006702.5) | Missense Mutation (SNP) | VAF 190/397 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POPDC2 | c.532T>A p.F178I | Missense Mutation (SNP) | VAF 10/283 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PXDNL | c.4043A>G p.E1348G | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- RBP3 | c.3550G>T p.D1184Y | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNASE3 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 205/701 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SART3 | c.2425-6C>T | Splice Region (SNP) | VAF 137/289 reads (47%) | called by muse, mutect2, varscan2
- SCEL | c.947T>C p.V316A (on ENST00000349847 / NM_144777.3; = p.V296A on NM_003843.4) | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SCRT2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEPSECS | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SETBP1 | c.4088A>C p.K1363T | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SI | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 132/233 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SKIDA1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 97/167 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SLC4A5 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 83/480 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SLC5A7 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 58/355 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SOX17 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 138/368 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- SPATS2L | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 321/323 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SPDEF | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 33/245 reads (13%) | called by muse, mutect2, varscan2
- SYNE1 | c.21673G>A p.E7225K (on ENST00000367255 / NM_182961.4; = p.E7154K on NM_033071.3) | Missense Mutation (SNP) | VAF 109/256 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- TAF1A | c.467del p.N156Ifs*2 | Frame Shift Del (DEL) | VAF 87/323 reads (27%) | called by mutect2, pindel, varscan2
- TLK2 | c.1831del p.I611Lfs*23 (on ENST00000326270 / NM_001284333.2; = p.I589Lfs*23 on NM_006852.6 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 47/182 reads (26%) | called by mutect2, pindel, varscan2
- TMEM151B | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TMEM184C | c.431T>C p.L144P | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- TMTC4 | c.849G>C p.M283I (on ENST00000376234 / NM_001350577.2; = p.M302I on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOGARAM1 | c.5058T>A p.F1686L | Missense Mutation (SNP) | VAF 109/231 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TOGARAM1 | c.5059G>T p.A1687S | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TRPM3 | c.4579T>A p.F1527I (on ENST00000357533 / NM_001366142.2; = p.F1382I on NM_020952.6) | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TSPEAR | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TWIST1 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 97/420 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYRO3 | c.362_365dup p.G123Wfs*3 | Frame Shift Ins (INS) | VAF 55/312 reads (18%) | called by pindel, varscan2
- USP9X | c.5974C>T p.R1992W | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UTRN | c.9932_9946del p.D3311_I3315del | In Frame Del (DEL) | VAF 143/451 reads (32%) | called by mutect2, pindel, varscan2
- VSIG10L | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- XIRP2 | c.3112A>C p.S1038R (on ENST00000628543; = p.S1213R on NM_152381.6) | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2
- YBEY | c.253del p.D85Tfs*9 | Frame Shift Del (DEL) | VAF 65/160 reads (41%) | called by mutect2, pindel, varscan2
- ZFPM2 | c.1650T>A p.C550* | Nonsense Mutation (SNP) | VAF 193/567 reads (34%) | called by muse, mutect2, varscan2
- ZNF292 | c.7139G>A p.S2380N | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF33A | c.1447C>G p.L483V (on ENST00000458705 / NM_006974.3; = p.L484V on NM_006954.2) | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF423 | c.3269T>G p.L1090R (on ENST00000563137 / NM_001379286.1; = p.L1082R on NM_015069.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF99 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 81/167 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- A4GALT | c.528C>T p.D176= | Silent (SNP) | VAF 220/455 reads (48%) | catalogued as COSV50744107; called by muse, mutect2, varscan2
- ACSM2B | c.1107T>G p.T369= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV61657267, COSV61658124; called by muse, mutect2, varscan2
- ADCY8 | c.1962T>C p.L654= | Silent (SNP) | VAF 24/752 reads (3%) | catalogued as COSV53911124; called by muse, mutect2
- ARFGEF1 | c.4158C>T p.L1386= | Silent (SNP) | VAF 51/190 reads (27%) | called by muse, mutect2, varscan2
- C3orf20 | c.2478G>A p.P826= | Silent (SNP) | VAF 115/216 reads (53%) | catalogued as rs369854080; called by muse, varscan2
- CASKIN1 | c.480C>T p.R160= | Silent (SNP) | VAF 128/260 reads (49%) | catalogued as rs1428439987, COSV58878374; called by muse, mutect2, varscan2
- CDH11 | c.1803G>T p.L601= | Silent (SNP) | VAF 60/225 reads (27%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.81G>A p.T27= | Silent (SNP) | VAF 69/371 reads (19%) | catalogued as rs1364100212; called by muse, mutect2, varscan2
- COMMD10 | c.486C>T p.L162= | Silent (SNP) | VAF 84/186 reads (45%) | catalogued as rs143206717; called by muse, mutect2, varscan2
- COP1 | c.522C>T p.N174= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV58165120; called by muse, mutect2
- CREBBP | c.2985G>T p.L995= | Silent (SNP) | VAF 144/501 reads (29%) | catalogued as COSV99270941; called by muse, mutect2, varscan2
- DCAF8L2 | c.775C>A p.R259= | Silent (SNP) | VAF 12/271 reads (4%) | catalogued as COSV101445783; called by muse, mutect2
- DENND11 | c.738C>T p.I246= | Silent (SNP) | VAF 74/75 reads (99%) | called by muse, mutect2, varscan2
- DOP1A | c.6105C>A p.V2035= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- DPAGT1 | c.1104T>C p.L368= | Silent (SNP) | VAF 124/704 reads (18%) | called by muse, mutect2, varscan2
- DZIP1L | c.120C>T p.T40= | Silent (SNP) | VAF 91/437 reads (21%) | catalogued as rs1263389751; called by muse, mutect2, varscan2
- FBH1 | c.2019G>A p.P673= (on ENST00000362091 / NM_178150.3; = p.P724= on NM_032807.4) | Silent (SNP) | VAF 73/276 reads (26%) | catalogued as rs138313303; called by muse, mutect2, varscan2
- FILIP1 | c.2991C>T p.G997= | Silent (SNP) | VAF 72/167 reads (43%) | catalogued as rs776433993, COSV52725047; called by muse, mutect2, varscan2
- FLNC | c.327C>T p.R109= | Silent (SNP) | VAF 139/524 reads (27%) | catalogued as rs750328194, COSV57960650; called by muse, mutect2, varscan2
- HDGFL1 | c.453C>T p.D151= | Silent (SNP) | VAF 102/118 reads (86%) | catalogued as rs1435183777; called by muse, varscan2
- IL1R1 | c.750C>A p.V250= | Silent (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
- IPPK | c.60C>T p.S20= | Silent (SNP) | VAF 102/237 reads (43%) | called by muse, mutect2, varscan2
- IRF4 | c.1011C>T p.D337= | Silent (SNP) | VAF 241/288 reads (84%) | catalogued as rs774672138, COSV66704578, COSV66705441; called by muse, mutect2, varscan2
- ITGAM | c.1374G>A p.G458= | Silent (SNP) | VAF 181/397 reads (46%) | called by muse, mutect2, varscan2
- KCNT1 | c.96C>T p.G32= | Silent (SNP) | VAF 164/380 reads (43%) | called by muse, mutect2, varscan2
- KERA | c.78C>A p.V26= | Silent (SNP) | VAF 48/94 reads (51%) | catalogued as rs1454197246; called by muse, mutect2, varscan2
- KIRREL3 | c.1224G>A p.G408= | Silent (SNP) | VAF 63/340 reads (19%) | called by muse, mutect2, varscan2
- LDHD | c.789C>T p.H263= | Silent (SNP) | VAF 136/207 reads (66%) | catalogued as rs145883732; called by muse, mutect2, varscan2
- MAGEC3 | c.207A>C p.G69= | Silent (SNP) | VAF 45/112 reads (40%) | called by muse, mutect2, varscan2
- MARCHF3 | c.168G>A p.V56= | Silent (SNP) | VAF 80/169 reads (47%) | catalogued as rs754247160; called by muse, mutect2
- MRTFA | c.402G>A p.P134= | Silent (SNP) | VAF 79/182 reads (43%) | catalogued as rs1218052040, COSV62936720; called by muse, mutect2, varscan2
- MUC22 | c.690C>T p.T230= | Silent (SNP) | VAF 42/229 reads (18%) | called by muse, mutect2, varscan2
- NPIPB11 | c.789C>T p.L263= | Silent (SNP) | VAF 400/600 reads (67%) | called by muse, varscan2
- OBSCN | c.1584C>T p.S528= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs754795176, COSV52776332; called by muse, mutect2
- OCEL1 | c.12G>C p.P4= | Silent (SNP) | VAF 169/358 reads (47%) | called by muse, mutect2, varscan2
- OR56A1 | c.450C>T p.F150= | Silent (SNP) | VAF 87/367 reads (24%) | called by muse, mutect2, varscan2
- OSBPL1A | c.1299G>A p.L433= | Silent (SNP) | VAF 81/155 reads (52%) | called by muse, mutect2, varscan2
- PAG1 | c.261C>G p.L87= | Silent (SNP) | VAF 111/304 reads (37%) | called by muse, varscan2
- PCDHA3 | c.795C>T p.N265= | Silent (SNP) | VAF 123/244 reads (50%) | called by muse, mutect2, varscan2
- PCDHB10 | c.2220C>T p.D740= | Silent (SNP) | VAF 102/226 reads (45%) | catalogued as COSV53378258; called by muse, varscan2
- PGR | c.1113C>T p.D371= | Silent (SNP) | VAF 134/545 reads (25%) | called by muse, mutect2, varscan2
- PNMA2 | c.933G>T p.R311= | Silent (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- PRAMEF8 | c.966G>A p.K322= | Silent (SNP) | VAF 218/1058 reads (21%) | called by muse, mutect2
- RNF19A | c.1531C>T p.L511= | Silent (SNP) | VAF 213/733 reads (29%) | called by muse, mutect2, varscan2
- RSKR | c.444C>A p.T148= | Silent (SNP) | VAF 124/421 reads (29%) | called by muse, mutect2, varscan2
- SLC7A7 | c.249C>T p.S83= | Silent (SNP) | VAF 130/393 reads (33%) | catalogued as rs146077876; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMARCC2 | c.3507A>G p.Q1169= | Silent (SNP) | VAF 15/403 reads (4%) | catalogued as COSV53237190; called by muse, mutect2
- SNRNP200 | c.4824G>A p.T1608= | Silent (SNP) | VAF 572/801 reads (71%) | catalogued as rs760963798, COSV60494866; called by muse, mutect2, varscan2
- SOX7 | c.918T>C p.P306= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2
- TBR1 | c.1440G>A p.S480= | Silent (SNP) | VAF 68/348 reads (20%) | called by muse, mutect2, varscan2
- TMEM178A | c.162C>T p.D54= | Silent (SNP) | VAF 24/531 reads (5%) | catalogued as rs1196821763, COSV56142368; called by muse, mutect2
- TRIM58 | c.228G>A p.A76= | Silent (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- URGCP | c.1011G>C p.L337= (on ENST00000453200 / NM_001077663.3; = p.L328= on NM_017920.4) | Silent (SNP) | VAF 161/539 reads (30%) | called by muse, mutect2, varscan2
- VAPB | c.174C>T p.S58= | Silent (SNP) | VAF 29/718 reads (4%) | catalogued as rs139149560; ClinVar: likely benign; called by muse, mutect2
- WDR17 | c.3508T>C p.L1170= | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- WDR97 | c.1098G>A p.A366= | Silent (SNP) | VAF 169/476 reads (36%) | catalogued as rs1186279774; called by muse, mutect2, varscan2
- ZCCHC8 | c.1704G>A p.P568= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs568770129, COSV60317601; called by muse, mutect2, varscan2
- ZMYND8 | c.2730C>T p.N910= (on ENST00000311275 / NM_001363741.2; = p.N884= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 528/769 reads (69%) | catalogued as rs779785588, COSV53685859; called by muse, mutect2, varscan2
- ZNF469 | c.2026C>T p.L676= | Silent (SNP) | VAF 211/469 reads (45%) | called by muse, mutect2, varscan2
- ZNF649 | c.1383G>A p.V461= | Silent (SNP) | VAF 262/596 reads (44%) | called by muse, mutect2, varscan2
- ZNF804B | c.534C>T p.S178= | Silent (SNP) | VAF 215/215 reads (100%) | catalogued as rs750948643; called by muse, mutect2, varscan2
- AC011487.2 | n.943C>A | RNA (SNP) | VAF 104/449 reads (23%) | called by muse, mutect2, varscan2
- AF121898.1 | n.205+24576T>G | Intron (SNP) | VAF 31/64 reads (48%) | called by muse, mutect2, varscan2
- AJAP1 | c.*5329T>G | 3'UTR (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100982318; called by muse, mutect2, varscan2
- AL033504.1 | n.117+76580A>C | Intron (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- AMPH | c.1182+414A>C | Intron (SNP) | VAF 49/348 reads (14%) | called by muse, mutect2, varscan2
- BOLA3 | c.*4C>T | 3'UTR (SNP) | VAF 102/366 reads (28%) | catalogued as rs191936501, COSV99768158; called by muse, mutect2, varscan2
- C5orf60 | n.2296C>T | RNA (SNP) | VAF 186/399 reads (47%) | called by muse, mutect2, varscan2
- C9orf78 | c.-36G>A | 5'UTR (SNP) | VAF 72/143 reads (50%) | catalogued as rs1399203071, COSV100204285, COSV100204629; called by muse, mutect2, varscan2
- CD200 | chr3:112333109 G>A | 5'Flank (SNP) | VAF 129/315 reads (41%) | catalogued as rs886532251; called by muse, mutect2, varscan2
- CFAP70 | c.3135+78dup | Intron (INS) | VAF 112/306 reads (37%) | catalogued as rs1392333409; called by mutect2, pindel, varscan2
- EDA2R | c.*19G>T | 3'UTR (SNP) | VAF 64/123 reads (52%) | called by muse, mutect2, varscan2
- EIF5AL1 | chr10:79510572 G>C | 5'Flank (SNP) | VAF 66/201 reads (33%) | called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2793T>C | Intron (SNP) | VAF 9/227 reads (4%) | called by muse, mutect2
- ESRRB | c.1296+265G>A | Intron (SNP) | VAF 135/307 reads (44%) | catalogued as rs576838853; called by muse, mutect2, varscan2
- ETS1 | chr11:128526998 G>C | 5'Flank (SNP) | VAF 175/246 reads (71%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.595G>A | RNA (SNP) | VAF 220/441 reads (50%) | catalogued as rs1455036920; called by muse, mutect2, varscan2
- FTH1 | chr11:61968340 del CGCCTCCCCGGGG | 5'Flank (DEL) | VAF 61/213 reads (29%) | called by mutect2, pindel, varscan2
- FXYD7 | c.61+65C>T | Intron (SNP) | VAF 104/153 reads (68%) | catalogued as rs765846996; called by muse, mutect2, varscan2
- GALNT9 | c.1077+254C>T | Intron (SNP) | VAF 55/123 reads (45%) | catalogued as rs1555238116; called by muse, mutect2, varscan2
- GNAT2 | c.*46C>T | 3'UTR (SNP) | VAF 90/183 reads (49%) | called by muse, mutect2, varscan2
- GREM1 | c.-2+243C>T | Intron (SNP) | VAF 120/265 reads (45%) | called by muse, mutect2, varscan2
- GRTP1 | c.921+17G>A | Intron (SNP) | VAF 36/388 reads (9%) | catalogued as rs1247718449; called by muse, mutect2
- HNF4A | c.1129+77C>T | Intron (SNP) | VAF 141/910 reads (15%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.-11A>G | 5'UTR (SNP) | VAF 88/163 reads (54%) | called by muse, mutect2, varscan2
- JAZF1-AS1 | n.753A>G | RNA (SNP) | VAF 88/352 reads (25%) | called by muse, mutect2, varscan2
- LAMA1 | c.345+24A>G | Intron (SNP) | VAF 203/204 reads (100%) | called by muse, mutect2, varscan2
- MTMR10 | c.-70G>A | 5'UTR (SNP) | VAF 64/109 reads (59%) | catalogued as rs1007543014, COSV71188902; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442904 T>G | 3'Flank (SNP) | VAF 13/168 reads (8%) | called by muse, mutect2
- NAP1L1 | c.1090-210A>C | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- NAP1L1 | c.1090-212C>A | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- PDGFA | c.580+16C>T | Intron (SNP) | VAF 252/790 reads (32%) | catalogued as rs763423914; called by muse, mutect2, varscan2
- PPP1R8 | c.-12G>A | 5'UTR (SNP) | VAF 29/231 reads (13%) | catalogued as rs772719531; called by muse, mutect2, varscan2
- PTGIS | c.*26C>T | 3'UTR (SNP) | VAF 149/1116 reads (13%) | called by muse, mutect2, varscan2
- RIPOR1 | c.-113C>T | 5'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2
- SNORD115-4 | n.44G>A | RNA (SNP) | VAF 115/256 reads (45%) | catalogued as rs1358756357; called by muse, mutect2, varscan2
- SPATA31C1 | n.2265T>C | RNA (SNP) | VAF 214/453 reads (47%) | catalogued as rs1249707076; called by muse, mutect2, varscan2
- TBC1D26 | c.198+22G>A | Intron (SNP) | VAF 56/120 reads (47%) | catalogued as rs770147407; called by muse, mutect2, varscan2
- TRIM5 | c.895+44A>G | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TRPA1 | c.-46C>T | 5'UTR (SNP) | VAF 103/265 reads (39%) | catalogued as rs1420999517; called by muse, mutect2, varscan2
- USP27X | chrX:49878659 G>A | 5'Flank (SNP) | VAF 253/548 reads (46%) | called by muse, mutect2, varscan2
- WNT10B | c.338-838_338-818del | Intron (DEL) | VAF 32/116 reads (28%) | called by mutect2, pindel, varscan2
